Somatic mutation profile of tumor specimen MBCProject_0589_T1_WES (aliquot MBCProject_0589_T1_WES_1) from CMI case MBCProject_0589, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 50.2 years (18,337 days).
Specimen MBCProject_0589_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d08233fb-f7be-40a6-a66b-eba841e43088.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0589_SALIVA (Saliva), aliquot MBCProject_0589_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c0f43e3-caa4-46ff-9346-c67498ca4da3

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Frame Shift Ins 5, Silent 4, Frame Shift Del 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP35 | c.4105C>T p.H1369Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1249121166; called by muse, mutect2, varscan2
- LAMA1 | c.3223G>T p.D1075Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV67539637; called by mutect2, varscan2
- LRRC41 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs1364789070; called by muse, mutect2, varscan2
- NF1 | c.730+1del | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | catalogued as CS086351, COSV62196345; called by mutect2, pindel
- NHLH1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1303382399, COSV57484449; called by muse, mutect2
- PCDH15 | c.4924G>A p.A1642T (on ENST00000644397 / NM_001354429.2; = p.A1584T on NM_001142771.2) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as rs748762813, COSV64685666; called by muse, mutect2, varscan2
- PTPRS | c.4448G>A p.R1483Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767215087; called by mutect2, varscan2
- CFAP44 | c.4017_4020dup p.E1341Ffs*4 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- GATA3 | c.1309del p.S437Afs*38 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
- GRHL2 | c.1398dup p.Y467Lfs*7 | Frame Shift Ins (INS) | VAF 17/111 reads (15%) | called by mutect2, pindel, varscan2
- ITGAD | c.2543T>A p.V848E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KPNA2 | c.1520T>C p.V507A | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEN1 | c.188dup p.Q64Pfs*53 | Frame Shift Ins (INS) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1701_1709del p.K567_L570delinsN (on ENST00000521381 / NM_181523.3; = p.K297_L300delinsN on NM_181504.4) | In Frame Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel
- RARA | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- STK11 | c.994dup p.W332Lfs*28 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- STK11 | c.995delinsTT p.W332Ffs*28 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by pindel, varscan2*
- TRIP4 | c.1551G>T p.L517F | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF595 | c.1639C>G p.R547G | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.215); called by muse, mutect2
- ZNF711 | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.935); called by mutect2, varscan2
- ZSWIM4 | c.301A>C p.T101P | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ENTPD7 | c.1779G>A p.E593= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- PBX3 | c.408G>A p.A136= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs777642477, COSV100655307; called by muse, mutect2, varscan2
- RAG1 | c.2775G>A p.T925= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs777246735, COSV55025926; called by muse, mutect2, varscan2
- ZBTB14 | c.777C>T p.A259= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs377633263; called by muse, mutect2, varscan2
- FTH1 | chr11:61968298 C>T | 5'Flank (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
